Somatic mutation profile of tumor specimen TCGA-W2-A7HH-01A (aliquot TCGA-W2-A7HH-01A-11D-A35I-08) from TCGA case TCGA-W2-A7HH, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 69.2 years (25,291 days).
Specimen TCGA-W2-A7HH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dac5eb27-7d0d-4778-a5c5-e70766040617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HH-10C (Blood Derived Normal), aliquot TCGA-W2-A7HH-10C-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee81daa4-e068-4023-8083-ab1df8d8edda

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAQR3 | c.50A>G p.Y17C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1172691522; called by muse, mutect2, varscan2
- RNLS | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59292469; called by muse, mutect2, varscan2
- CC2D2A | c.678A>C p.E226D | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTCF | c.771T>G p.I257M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GSTA3 | c.496T>A p.Y166N | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2
- NEDD9 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- POLR1A | c.2566A>G p.R856G | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RPGR | c.2520+8A>C | Splice Region (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- SCN2A | c.1414A>G p.R472G | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- TFAP2C | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FUT5 | c.180T>C p.N60= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- OAS2 | c.1284G>A p.R428= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
